Somatic mutation profile of tumor specimen MP2PRT-PAPLTR-TMP1-A (aliquot MP2PRT-PAPLTR-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPLTR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Subacute lymphoid leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,430 days).
Specimen MP2PRT-PAPLTR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b3a27c3-1b64-467f-8bbe-c23223135295.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPLTR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPLTR-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64c4caf4-8cb3-46ec-b44e-cf8268ec5dfe

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Nonsense Mutation 4, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C19orf81 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 55/456 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs1185910805; called by muse, mutect2, varscan2
- DST | c.4076C>G p.S1359* (on ENST00000361203 / NM_001374722.1; = p.S1033* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 58/309 reads (19%) | catalogued as COSV55032922; called by muse, mutect2, varscan2
- FAM83B | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 148/475 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.046); catalogued as COSV100174753; called by muse, mutect2, varscan2
- FAXC | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 111/554 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs769078040, COSV67603292; called by muse, mutect2, varscan2
- GPR180 | c.568C>G p.Q190E | Missense Mutation (SNP) | VAF 57/466 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as COSV65385259; called by muse, mutect2, varscan2
- H1-6 | c.470G>A p.R157K | Missense Mutation (SNP) | VAF 120/431 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs781379569; called by muse, mutect2, varscan2
- H2BC4 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 79/220 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV58415640; called by muse, mutect2, varscan2
- IL17C | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 103/353 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs1225234426; called by muse, mutect2, varscan2
- KSR2 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 22/367 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV56667040; called by muse, mutect2
- MTNR1B | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 210/694 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1451347407, COSV57068780; called by muse, mutect2
- SELE | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 55/335 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs776079701, COSV60975206; called by muse, mutect2, varscan2
- TAS2R40 | c.831G>A p.W277* | Nonsense Mutation (SNP) | VAF 100/335 reads (30%) | catalogued as rs866765172; called by muse, mutect2, varscan2
- EZHIP | c.1189T>C p.S397P | Missense Mutation (SNP) | VAF 199/620 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HSPH1 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 90/296 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NAALADL2 | c.164A>G p.E55G | Missense Mutation (SNP) | VAF 110/367 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NFATC1 | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 78/275 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TCAF2 | c.758C>A p.S253* | Nonsense Mutation (SNP) | VAF 24/385 reads (6%) | called by muse, mutect2
- TMPRSS13 | c.1727C>G p.S576* | Nonsense Mutation (SNP) | VAF 38/649 reads (6%) | called by muse, mutect2
- YY1 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 109/422 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ABL1 | c.1110G>A p.L370= | Silent (SNP) | VAF 120/363 reads (33%) | catalogued as COSV59331593; called by muse, mutect2, varscan2
- CKAP4 | c.1422C>T p.S474= | Silent (SNP) | VAF 175/579 reads (30%) | called by muse, mutect2, varscan2
- SEPTIN6 | c.9G>A p.A3= | Silent (SNP) | VAF 49/614 reads (8%) | called by muse, mutect2
- TMEFF1 | c.100C>T p.L34= | Silent (SNP) | VAF 97/759 reads (13%) | catalogued as rs774030608; called by muse, mutect2, varscan2
- ZFHX4 | c.1932C>G p.L644= | Silent (SNP) | VAF 95/304 reads (31%) | called by muse, mutect2, varscan2
- REXO1L1P | n.96G>A | RNA (SNP) | VAF 35/1180 reads (3%) | called by muse, mutect2
- TTC39C | c.167+1645G>A | Intron (SNP) | VAF 95/321 reads (30%) | catalogued as rs1319241886; called by muse, mutect2, varscan2
- YTHDF3 | c.50-2563C>T | Intron (SNP) | VAF 34/422 reads (8%) | called by muse, mutect2
